Gene-level copy-number profile of tumor specimen TCGA-VR-A8ET-01A from TCGA case TCGA-VR-A8ET, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 64.4 years (23,517 days).
Specimen TCGA-VR-A8ET-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.1921e9cc-572e-4761-b507-a5f71f5e1e89.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VR-A8ET-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2.
https://portal.gdc.cancer.gov/files/83994f1a-47e4-4e73-877c-8a26218d087c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 4,495; copy number 2: 52,307; copy number 3: 2,596; copy number 5: 4; copy number 7: 3; copy number 8: 49; copy number 9: 113; copy number 10: 2; copy number 11: 90; copy number 12: 38; copy number 13: 23; copy number 16: 33; copy number 17: 10; copy number 18: 10; copy number 19: 10; copy number 22: 33.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 418 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:80,245,926–80,974,724, 10 genes, copy number 17: RN7SL869P, AC003988.1, AC004862.1, RN7SL35P, CD36, SNRPBP1, GNAT3, AC073850.1, SEMA3C, AC004972.1.
- chr7:84,847,877–96,322,147, 156 genes, copy number 7–19 (within-gene range 2–19) (broad region; genes not listed).
- chr7:96,481,626–98,209,638, 33 genes, copy number 16 (within-gene range 1–16): SEM1, MARK2P10, RN7SL252P, DLX6-AS1, AC004774.1, AC004774.3, DLX6, AC004774.2, DLX5, SDHAF3, HMGB3P21, AC073900.1, AP1S2P1, RN7SKP104, TAC1, ASNS, AC079781.5, AC005326.1, SNRPCP9, RPS3AP29, AC079781.1, AC079781.2, AC079781.4, AC079781.3, OR7E7P, MIR5692A1, MIR5692C2, OR7E38P, AC004967.2, AC004967.1, OCM2, RN7SL478P, LMTK2.
- chr12:42,069,935–42,144,874, 2 genes, copy number 10 (within-gene range 2–10): AC023513.1, GXYLT1.
- chr12:50,504,985–52,015,889, 49 genes, copy number 8 (within-gene range 2–8): DIP2B, RNU6-769P, RNU6-238P, Y_RNA, AC013244.1, ATF1, AC013244.2, RN7SL519P, TMPRSS12, AC013244.3, METTL7A, AC008121.2, Y_RNA, AC008121.1, HIGD1C, AC008121.3, SLC11A2, RNU6-87P, RNU6-1273P, LETMD1, CSRNP2, TFCP2, RPL35AP29, PHBP19, Y_RNA, RNU6-199P, POU6F1, AC139768.1, DAZAP2, SMAGP, BIN2, CELA1, GALNT6, SLC4A8, AC107031.1, SCN8A, HNRNPA3P10, AC068987.1, TMDD1, AC068987.2, FIGNL2, AC068987.3, FIGNL2-DT, ANKRD33, AC025259.2, ACVRL1, ACVR1B, RNU6-574P, TAMALIN.
- chr12:62,935,701–69,959,097, 167 genes, copy number 5–22 (broad region; genes not listed).
- chr12:69,946,543–69,947,081, 1 gene, copy number 13: AC078922.1.

Autosomal genes at a single copy (total copy number 1): 2,078. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
